Somatic mutation profile of tumor specimen TCGA-L5-A4OM-01A (aliquot TCGA-L5-A4OM-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OM, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 54.3 years (19,845 days).
Specimen TCGA-L5-A4OM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce898293-1c0e-4131-8a8e-02072c24fe13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OM-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OM-11A-11D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddbfdb70-6b25-4247-94f3-3f3a92672cd8

The open-access MAF lists 72 somatic variants for this specimen: 58 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 12, Splice Site 2, 3'UTR 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as COSV52518005, COSV99451705; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 355/441 reads (80%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADH6 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778701583, COSV52956709; called by muse, mutect2, varscan2
- AMER2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs745945541, COSV63437872; called by muse, mutect2, varscan2
- AP3B2 | c.2014_2016del p.E672del | In Frame Del (DEL) | VAF 20/61 reads (33%) | catalogued as rs765815539; called by mutect2, pindel, varscan2
- CDHR5 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs774600340; called by muse, mutect2, varscan2
- COLGALT2 | c.1603G>T p.V535L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.334); catalogued as COSV100730640; called by muse, varscan2
- DBF4 | c.1445A>G p.Y482C | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs373255355; called by muse, mutect2, varscan2
- FAM83G | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58758946; called by muse, mutect2
- FASN | c.7426G>A p.V2476I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1140623, COSV60750494; called by muse, mutect2, varscan2
- GLUD2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100046725; called by muse, mutect2, varscan2
- OLA1 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs761407656; called by muse, mutect2, varscan2
- PJA1 | c.332G>T p.R111I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100824701, COSV64053838; called by muse, mutect2, varscan2
- PLA2G7 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99221634; called by muse, mutect2, varscan2
- PPP1R15A | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52340236; called by muse, mutect2, varscan2
- PRR5L | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.119); catalogued as rs1227303624, COSV100286946, COSV61120391; called by muse, mutect2, varscan2
- PTPRD | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61930987; called by muse, mutect2, varscan2
- RTN1 | c.598A>C p.T200P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs767482992, COSV50736057; called by muse, mutect2, varscan2
- SH3BP5L | c.638A>T p.K213M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1361368175; called by muse, mutect2, varscan2
- SULT1A1 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs767993186, COSV59090887; called by muse, mutect2, varscan2
- TCF7L1 | c.617C>A p.S206Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV56403781; called by muse, mutect2, varscan2
- TCOF1 | c.3574G>A p.E1192K (on ENST00000377797 / NM_001135243.1; = p.E1115K on NM_000356.4) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs751297952, COSV60349960; called by muse, mutect2, varscan2
- ZDHHC11 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 6/165 reads (4%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV99362802; called by muse, mutect2
- ZNF208 | c.2281T>C p.S761P | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1360288573; called by muse, mutect2, varscan2
- ZNF697 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70284281; called by muse, mutect2, varscan2
- AASDH | c.2123C>A p.S708Y | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- ALDH6A1 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD40 | c.785T>G p.V262G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATG5 | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- BIRC6 | c.10241T>C p.L3414S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2
- CDC42BPG | c.710A>T p.Y237F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- CFAP65 | c.1213C>A p.Q405K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CSAG3 | c.155A>G p.D52G | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- EEFSEC | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FEM1C | c.1407A>G p.I469M | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- HTT | c.2086G>A p.G696R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- KCTD19 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- LIN7A | c.509A>C p.K170T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- LY75 | c.4822G>C p.D1608H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MIB1 | c.2432A>T p.N811I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MICAL3 | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MPZL1 | c.258_258+18del p.X86_splice | Splice Site (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- MTA2 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MTUS2 | c.2563G>A p.V855I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- NCAN | c.453C>A p.D151E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- OR11L1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- OR4C46 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PGF | c.588C>A p.N196K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PUM3 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- RAPGEF1 | c.163A>G p.R55G | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SCN2A | c.269C>A p.T90K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC39A12 | c.1925T>C p.L642S (on ENST00000377369 / NM_001145195.2; = p.L605S on NM_152725.3) | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TARS1 | c.990A>T p.Q330H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2
- TBCK | c.2402A>G p.N801S (on ENST00000273980 / NM_001163436.4; = p.N738S on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM127 | c.614A>G p.E205G | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2
- YY1AP1 | c.1574C>G p.S525C (on ENST00000295566 / NM_139118.2; = p.S468C on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- ZNF445 | c.1859C>T p.T620I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN29 | c.1796G>T p.R599L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CLGN | c.615C>T p.F205= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs749787516, COSV57774342; called by muse, mutect2, varscan2
- H3-3A | c.27C>T p.R9= | Silent (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- HECTD4 | c.1677A>G p.S559= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs373751710; called by muse, mutect2, varscan2
- IGHV3-11 | c.351A>G p.R117= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs201985526; called by muse, mutect2
- KIAA1210 | c.4818C>A p.A1606= | Silent (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- OR2AG2 | c.543C>T p.I181= | Silent (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- PUM3 | c.813G>T p.L271= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- PUM3 | c.360G>A p.L120= | Silent (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- SIGLEC6 | c.528G>A p.T176= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs758976882, COSV58434147; called by muse, mutect2, varscan2
- TTN | c.18585T>C p.A6195= (on ENST00000591111; = p.A5268= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- ZNF385A | c.918C>T p.A306= (on ENST00000338010 / NM_001130967.3; = p.A286= on NM_015481.3) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs752247719; called by muse, varscan2
- ZNF512B | c.1947G>A p.V649= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- LARS2 | c.*364G>A | 3'UTR (SNP) | VAF 20/39 reads (51%) | catalogued as rs189078355, COSV55531791; called by muse, mutect2, varscan2
- PROX2 | c.*903T>A | 3'UTR (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
